Somatic mutation profile of tumor specimen C3N-00560-02 (aliquot CPT0068800006) from CPTAC case C3N-00560, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.8 years (20,372 days).
Specimen C3N-00560-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cbff655-9909-489d-970b-c3e5536ab530.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00560-71 (Blood Derived Normal), aliquot CPT0068910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9df44fd8-425a-4334-8f25-b8dcdc58a87b

The open-access MAF lists 1,596 somatic variants for this specimen: 1,097 protein-altering or splice-affecting, 300 silent, 199 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 924, Silent 300, Intron 98, Nonsense Mutation 75, RNA 41, Splice Site 38, Frame Shift Del 34, 5'UTR 20, 3'UTR 18, 5'Flank 13, Splice Region 12, Frame Shift Ins 11.

Variants (750 of 1,596; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K2 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880511, COSV53566038; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PDE6C | c.724-1G>T p.X242_splice | Splice Site (SNP) | VAF 66/262 reads (25%) | catalogued as rs1057518244; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>T p.X126_splice | Splice Site (SNP) | VAF 190/315 reads (60%) | hotspot (GDC flag); catalogued as CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; called by muse, mutect2, varscan2
- A2ML1 | c.724T>C p.C242R | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs777559324; called by muse, mutect2, varscan2
- ABCA3 | c.4652G>T p.R1551L | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57054460; called by muse, mutect2, varscan2
- ABCA4 | c.3967G>C p.G1323R | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64676623; called by muse, mutect2, varscan2
- ABR | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as rs369724938; called by muse, mutect2, varscan2
- ACHE | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as COSV53819220; called by muse, mutect2
- ACTN2 | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 285/466 reads (61%) | catalogued as COSV63977536; called by muse, mutect2, varscan2
- ADAM12 | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372825649; called by muse, mutect2, varscan2
- ADAM17 | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60402465; called by muse, varscan2
- ADAMTS16 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56987127; called by muse, mutect2, varscan2
- ADGRE1 | c.345del p.T116Lfs*95 | Frame Shift Del (DEL) | VAF 97/211 reads (46%) | catalogued as COSV51676264; called by mutect2, pindel, varscan2
- ADGRE2 | c.2305C>A p.L769M | Missense Mutation (SNP) | VAF 99/186 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59692087; called by muse, mutect2, varscan2
- ADNP2 | c.1847C>A p.T616K | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51536502; called by muse, mutect2, varscan2
- AGT | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 162/599 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145882750, COSV99080837; called by muse, mutect2, varscan2
- AKAP12 | c.1874G>C p.R625P | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53574413; called by muse, mutect2, varscan2
- AKAP9 | c.2137A>T p.K713* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV62349662; called by muse, mutect2, varscan2
- AMDHD2 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV53552120, COSV99565622; called by muse, mutect2, varscan2
- ANK2 | c.10163G>A p.S3388N | Missense Mutation (SNP) | VAF 120/264 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as rs772158824; called by muse, mutect2, varscan2
- ANK3 | c.5542T>G p.S1848A | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs1007940222; called by muse, mutect2, varscan2
- ANKRD24 | c.2890C>G p.L964V | Missense Mutation (SNP) | VAF 101/203 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs752175749; called by muse, mutect2, varscan2
- ANKRD30B | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as rs1262559327; called by muse, mutect2, varscan2
- ANO10 | c.1615A>G p.R539G | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs755556322; called by muse, mutect2, varscan2
- AP1B1 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247355431; called by muse, mutect2, varscan2
- APCDD1L | c.969C>A p.C323* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV64485208; called by muse, mutect2, varscan2
- APOB | c.8530C>A p.L2844M | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV51930748; called by muse, mutect2, varscan2
- AQP10 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV100270347; called by muse, mutect2, varscan2
- ARHGAP22 | c.1336G>C p.G446R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs766621193; called by muse, mutect2, varscan2
- ARHGAP9 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.335); catalogued as COSV99954440; called by muse, mutect2, varscan2
- ARHGEF38 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 240/485 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1366384114; called by muse, mutect2, varscan2
- ARID1A | c.3326G>T p.R1109L | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61388306; called by muse, mutect2, varscan2
- ASTN2 | c.3696G>T p.M1232I (on ENST00000313400 / NM_001365069.1; = p.M1181I on NM_014010.5) | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV55999327; called by muse, mutect2, varscan2
- ATXN1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs767284664; called by muse, mutect2, varscan2
- BCHE | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs765307050, COSV52259530; called by muse, mutect2, varscan2
- BICD1 | c.1963G>T p.A655S | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV55676878; called by muse, mutect2, varscan2
- BMPER | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 229/797 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs866309179, COSV99780621; called by muse, mutect2, varscan2
- BNC1 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100597000; called by muse, mutect2, varscan2
- BPIFB2 | c.1049C>A p.S350* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs375053033; called by muse, mutect2, varscan2
- BPNT1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755692625; called by muse, mutect2, varscan2
- BRCA1 | c.3508A>T p.I1170F | Missense Mutation (SNP) | VAF 132/445 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs273899708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUD23 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as rs782799925; called by muse, mutect2, varscan2
- C1QTNF9 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59656964, COSV59657345; called by muse, mutect2, varscan2
- C1orf105 | c.199-1G>C p.X67_splice | Splice Site (SNP) | VAF 32/109 reads (29%) | catalogued as COSV62959323; called by muse, mutect2, varscan2
- C21orf62 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs553714757; called by muse, mutect2, varscan2
- C6 | c.2517C>A p.D839E | Missense Mutation (SNP) | VAF 104/712 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV54707923; called by muse, mutect2, varscan2
- C7 | c.1543G>T p.G515W | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57479431; called by muse, mutect2, varscan2
- CACNA1A | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803432; called by muse, mutect2, varscan2
- CACNA2D1 | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV62377292; called by muse, varscan2
- CACNG1 | c.425T>C p.M142T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1336931204; called by muse, mutect2, varscan2
- CAGE1 | c.742G>T p.V248F (on ENST00000512086; = p.V112F on NM_205864.3) | Missense Mutation (SNP) | VAF 122/164 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV57076575; called by muse, mutect2, varscan2
- CALB1 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs371813448; called by muse, mutect2, varscan2
- CAMK2B | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1327333288; called by muse, mutect2, varscan2
- CCDC178 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779422806, COSV55761954; called by muse, mutect2, varscan2
- CCDC80 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs752186550; called by muse, mutect2, varscan2
- CCDC9 | c.365G>C p.G122A | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV55719663; called by muse, mutect2, varscan2
- CD101 | c.1966C>A p.P656T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1417399215; called by muse, mutect2, varscan2
- CDC5L | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 119/217 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV65175107, COSV65177679; called by muse, mutect2, varscan2
- CDH18 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56923309; called by muse, mutect2, varscan2
- CDH24 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212611350; called by muse, mutect2, varscan2
- CDON | c.1464G>T p.Q488H | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs754643422; called by muse, mutect2, varscan2
- CEBPE | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV52829693; called by muse, mutect2, varscan2
- CHAT | c.1668C>A p.S556R | Missense Mutation (SNP) | VAF 89/455 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs55702495, COSV100339693, COSV60324581; called by muse, mutect2, varscan2
- CHRM2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 124/501 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57780539; called by muse, mutect2, varscan2
- CLEC12B | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs746531340; called by mutect2, varscan2
- CLEC4E | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1018548251; called by muse, mutect2, varscan2
- CLEC4F | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV55478761; called by muse, mutect2, varscan2
- CMKLR1 | c.746G>T p.R249L (on ENST00000312143 / NM_001142344.2; = p.R247L on NM_004072.3) | Missense Mutation (SNP) | VAF 135/277 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100379365; called by muse, mutect2, varscan2
- COG4 | c.1590A>T p.Q530H | Missense Mutation (SNP) | VAF 202/423 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV100092090; called by muse, mutect2, varscan2
- COL11A1 | c.1987C>A p.P663T | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV62183756; called by muse, mutect2, varscan2
- COL11A1 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV62201515; called by muse, mutect2, varscan2
- COL12A1 | c.6067+1G>T p.X2023_splice | Splice Site (SNP) | VAF 83/135 reads (61%) | catalogued as COSV59405148; called by muse, mutect2, varscan2
- COL2A1 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 76/385 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100475856, COSV61529027; called by muse, mutect2, varscan2
- COL5A2 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879988, COSV100880820; called by muse, mutect2, varscan2
- COL5A3 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs758573683; called by muse, mutect2, varscan2
- COL9A3 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1007898382, COSV100101717, COSV58986363; called by muse, mutect2, varscan2
- CPEB4 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs753884175; called by muse, mutect2, varscan2
- CRLF1 | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1215825108; called by muse, mutect2
- CSF2RA | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 117/915 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62625085; called by muse, mutect2, varscan2
- CSMD1 | c.2482G>T p.E828* (on ENST00000520002; = p.E827* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | catalogued as COSV59390189; called by muse, mutect2, varscan2
- CSMD2 | c.9559+1G>T p.X3187_splice | Splice Site (SNP) | VAF 45/138 reads (33%) | catalogued as COSV53910136; called by muse, mutect2, varscan2
- CSN1S1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs567240015; called by muse, mutect2, varscan2
- CTH | c.1052+1G>T p.X351_splice | Splice Site (SNP) | VAF 44/409 reads (11%) | catalogued as COSV61008491; called by muse, mutect2, varscan2
- CUBN | c.5396G>T p.R1799L | Missense Mutation (SNP) | VAF 94/289 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100911968; called by muse, mutect2, varscan2
- CYLD | c.2296T>C p.F766L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV100282361; called by muse, mutect2, varscan2
- CYP11B2 | c.101C>A p.T34K | Missense Mutation (SNP) | VAF 190/609 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.716); catalogued as COSV59995329; called by muse, mutect2, varscan2
- CYP26C1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as rs762928955, COSV53651885; called by muse, mutect2, varscan2
- CYP2W1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.279); catalogued as COSV100417118; called by muse, mutect2, varscan2
- CYP51A1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV50150960; called by muse, mutect2, varscan2
- DACH2 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs1267245491, COSV100912578; called by muse, mutect2, varscan2
- DCC | c.72C>G p.S24R | Missense Mutation (SNP) | VAF 152/599 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV101472574; called by muse, mutect2, varscan2
- DCC | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59117180; called by muse, mutect2, varscan2
- DDX41 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV57253707; called by muse, mutect2, varscan2
- DHRS7C | c.401G>T p.G134V (on ENST00000330255 / NM_001220493.2; = p.G133V on NM_001105571.3) | Missense Mutation (SNP) | VAF 298/486 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV57653075; called by mutect2, varscan2
- DKK2 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 136/216 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as rs34890926; called by muse, mutect2, varscan2
- DNAH5 | c.5710-2A>T p.X1904_splice | Splice Site (SNP) | VAF 68/298 reads (23%) | catalogued as CS091944; called by muse, mutect2, varscan2
- DOK7 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100403096; called by muse, mutect2, varscan2
- DPYSL4 | c.183C>G p.H61Q | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.053); catalogued as COSV100633942; called by muse, mutect2, varscan2
- DTNA | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 100/403 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99314250; called by muse, mutect2, varscan2
- DTNA | c.523del p.L175Sfs*32 | Frame Shift Del (DEL) | VAF 95/352 reads (27%) | catalogued as COSV99315270; called by mutect2, pindel, varscan2
- DTX4 | c.1737G>T p.K579N | Missense Mutation (SNP) | VAF 139/301 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104390074; called by muse, mutect2, varscan2
- DUSP18 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1169738683; called by muse, mutect2, varscan2
- DYRK4 | c.999G>T p.R333S | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99155200; called by muse, mutect2, varscan2
- EBAG9 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as rs1255404229; called by muse, mutect2, varscan2
- ECD | c.1624C>A p.L542I | Missense Mutation (SNP) | VAF 160/436 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as rs1169360677; called by muse, mutect2, varscan2
- EFCAB6 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | catalogued as rs1488712423; called by muse, mutect2, varscan2
- EIF3B | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 179/600 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV62803468; called by muse, mutect2, varscan2
- EPHA5 | c.1408T>C p.S470P | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs1349192633; called by muse, mutect2, varscan2
- EXT1 | c.1745G>T p.W582L | Missense Mutation (SNP) | VAF 67/500 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM012094; called by muse, varscan2
- FAM110C | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.856); catalogued as COSV59655692; called by muse, mutect2, varscan2
- FAM135B | c.1356C>A p.S452R | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52743093; called by muse, mutect2, varscan2
- FAM186A | c.3849G>T p.Q1283H | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59253164; called by muse, mutect2, varscan2
- FAM216B | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs749283387, COSV58270230; called by muse, mutect2, varscan2
- FAM47C | c.1143A>C p.E381D | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV63725490; called by muse, varscan2
- FAM47C | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 82/154 reads (53%) | catalogued as COSV63728168; called by muse, varscan2
- FAM71F1 | c.494A>T p.Q165L | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV59375142; called by muse, mutect2, varscan2
- FAT3 | c.7504G>T p.V2502L | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as COSV53071433, COSV53099482; called by muse, mutect2, varscan2
- FAT4 | c.5647G>T p.D1883Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58701982; called by muse, mutect2, varscan2
- FBN2 | c.4657C>G p.R1553G | Missense Mutation (SNP) | VAF 155/324 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as rs370210353, CM158364; called by muse, mutect2, varscan2
- FBXL7 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV100309120; called by muse, mutect2, varscan2
- FCRL4 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 118/345 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54864083; called by muse, mutect2, varscan2
- FER1L6 | c.4510C>G p.Q1504E | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs377046476; called by muse, mutect2, varscan2
- FGFR2 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 116/404 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs200766273, COSV60646540, COSV60647757; called by muse, mutect2, varscan2
- FLG | c.231G>C p.M77I | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs1358450049; called by muse, mutect2, varscan2
- FNDC8 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV99338694; called by muse, mutect2, varscan2
- FOXF2 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 202/313 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52525422; called by muse, mutect2, varscan2
- FPR3 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs147264707; called by muse, mutect2
- GABRB3 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 115/252 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100161499; called by muse, mutect2, varscan2
- GANC | c.2594G>C p.G865A | Missense Mutation (SNP) | VAF 59/139 reads (42%) | PolyPhen probably damaging (0.962); catalogued as COSV100531325; called by muse, mutect2, varscan2
- GCG | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100972856; called by muse, mutect2, varscan2
- GLI1 | c.2095G>T p.D699Y | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV57358039; called by muse, mutect2, varscan2
- GLIS1 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100389552; called by muse, mutect2, varscan2
- GMNC | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV71248986; called by muse, mutect2
- GNAS | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 243/836 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); catalogued as rs747313993, COSV58332285; called by muse, mutect2, varscan2
- GPR85 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51783474, COSV51785882; called by muse, mutect2, varscan2
- GRIA3 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866395967; called by muse, mutect2
- GRIN2B | c.2360G>A p.G787E | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74208425; called by muse, mutect2, varscan2
- GTF3C2 | c.1630G>C p.G544R | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99273292; called by muse, mutect2, varscan2
- GUCY1A2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.007); catalogued as rs1317434872; called by muse, mutect2, varscan2
- H2BC5 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 92/148 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as rs368384735, COSV56803612; called by muse, varscan2
- H2BC5 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 154/263 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs776467875; called by muse, varscan2
- HABP2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.079); catalogued as COSV63635936; called by muse, mutect2, varscan2
- HERC2 | c.1971G>T p.L657F | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV55311317; called by muse, mutect2, varscan2
- HNF1A | c.1427T>A p.L476H | Missense Mutation (SNP) | VAF 139/309 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57465726; called by muse, mutect2, varscan2
- HSPG2 | c.12223G>T p.G4075C | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60828482; called by muse, mutect2, varscan2
- HUS1B | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.251); catalogued as rs753225884, COSV57868858; called by muse, mutect2, varscan2
- IGKV3-11 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 117/625 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); catalogued as rs532970070; called by muse, mutect2, varscan2
- IGLV2-11 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.585); catalogued as rs9612149; called by muse, mutect2, varscan2
- INPP4A | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1379669602, COSV50784869; called by muse, mutect2, varscan2
- INPP4B | c.2115G>C p.L705F | Missense Mutation (SNP) | VAF 127/210 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99526028; called by muse, mutect2, varscan2
- INSR | c.2743G>T p.G915W | Missense Mutation (SNP) | VAF 221/385 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV57168790; called by muse, mutect2, varscan2
- IQUB | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs538267953; called by muse, mutect2, varscan2
- IRS2 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 301/433 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65478895; called by muse, mutect2, varscan2
- ISL2 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1467086035; called by muse, mutect2, varscan2
- ITGAL | c.2905C>A p.L969M | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV63321739; called by muse, mutect2, varscan2
- ITPKB | c.1980C>A p.F660L | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as COSV55257983; called by muse, mutect2, varscan2
- ITPR1 | c.2195G>T p.S732I (on ENST00000354582; = p.S717I on NM_002222.7) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV56983474; called by muse, mutect2
- IWS1 | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs550032523; called by muse, mutect2, varscan2
- JPH4 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1229942767; called by muse, mutect2, varscan2
- JRK | c.1575G>T p.Q525H | Missense Mutation (SNP) | VAF 109/206 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV101401170; called by muse, mutect2, varscan2
- KCNA4 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV60255261; called by muse, mutect2, varscan2
- KIAA1549L | c.221G>C p.S74T (on ENST00000321505; = p.S371T on NM_012194.3) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55777085; called by muse, mutect2, varscan2
- KRT37 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 176/643 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV99845258; called by muse, mutect2, varscan2
- L3MBTL1 | c.1728G>T p.W576C (on ENST00000418998 / NM_001377303.1; = p.W486C on NM_015478.7) | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917003; called by muse, mutect2, varscan2
- LAMA1 | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200844421, COSV67539030; called by muse, mutect2, varscan2
- LAMA2 | c.2770G>T p.G924C | Missense Mutation (SNP) | VAF 212/404 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101370719; called by muse, mutect2, varscan2
- LAMC3 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 146/493 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167109596; called by muse, mutect2, varscan2
- LAMP2 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52351344; called by muse, mutect2, varscan2
- LIPK | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV101345002; called by muse, mutect2, varscan2
- LMOD2 | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV71755655; called by muse, mutect2, varscan2
- LOXHD1 | c.2437+1G>T p.X813_splice | Splice Site (SNP) | VAF 20/78 reads (26%) | catalogued as rs1474677081; called by muse, varscan2
- LPAR5 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs900370196; called by muse, varscan2
- LRFN4 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162648844, COSV58921608; called by muse, mutect2, varscan2
- LRRTM1 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV99702312; called by muse, mutect2, varscan2
- LRRTM3 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792017; called by muse, mutect2, varscan2
- LY9 | c.1022C>G p.S341* | Nonsense Mutation (SNP) | VAF 66/217 reads (30%) | catalogued as rs750028876; called by muse, mutect2, varscan2
- MAGI1 | c.758C>G p.A253G | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs772043382; called by muse, mutect2, varscan2
- MAL | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV59431182; called by muse, mutect2, varscan2
- MAP3K9 | c.2381G>T p.R794L (on ENST00000554752 / NM_001284230.1; = p.R808L on NM_033141.4) | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as COSV101173656, COSV67120956; called by muse, mutect2, varscan2
- MAPT | c.1900C>A p.R634S (on ENST00000262410 / NM_001377265.1; = p.R242S on NM_005910.5) | Missense Mutation (SNP) | VAF 116/506 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99289572; called by muse, mutect2, varscan2
- MASP1 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 123/320 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1421663836; called by muse, mutect2, varscan2
- MCCC1 | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 144/398 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV55612981; called by muse, mutect2, varscan2
- MED24 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as rs779781361; called by muse, mutect2, varscan2
- MKKS | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as rs200322204; called by muse, mutect2, varscan2
- MRGPRF | c.883G>C p.G295R | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99070096; called by muse, mutect2, varscan2
- MRPL38 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV58614992; called by muse, mutect2, varscan2
- MYO16 | c.2221del p.A741Pfs*13 | Frame Shift Del (DEL) | VAF 111/217 reads (51%) | catalogued as COSV51815599; called by mutect2, pindel, varscan2
- MYO18B | c.5180G>T p.R1727L | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59142285; called by muse, mutect2, varscan2
- MYO18B | c.7350G>T p.K2450N | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs779452112; called by muse, mutect2, varscan2
- NBEAL1 | c.4595C>T p.S1532L | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV71374749; called by muse, mutect2, varscan2
- NCAN | c.3875A>T p.Q1292L | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV53048609; called by muse, mutect2, varscan2
- NETO2 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.453); catalogued as rs572763783, COSV57452054; called by muse, mutect2, varscan2
- NFATC4 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 138/485 reads (28%) | catalogued as COSV51596706; called by muse, varscan2
- NLGN4X | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 103/170 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99321990; called by muse, mutect2, varscan2
- NPAS3 | c.1235C>A p.A412D (on ENST00000356141 / NM_001164749.2; = p.A380D on NM_022123.3) | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100640214, COSV60841832; called by muse, mutect2, varscan2
- NPAS4 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 139/288 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs777027579, COSV60650844; called by muse, mutect2, varscan2
- NRK | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV104388016; called by muse, mutect2, varscan2
- NSG2 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs770414388; called by muse, mutect2, varscan2
- NXPE4 | c.1047G>T p.M349I (on ENST00000375478 / NM_001077639.2; = p.M65I on NM_017678.3) | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV64944408; called by muse, mutect2, varscan2
- OGDHL | c.2185C>T p.L729F | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs778419863; called by muse, mutect2, varscan2
- OLFML2B | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV54193730; called by muse, mutect2, varscan2
- ONECUT2 | c.1470C>A p.S490R | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.368); catalogued as COSV101525743; called by muse, mutect2, varscan2
- OR1L1 | c.248C>T p.P83L (on ENST00000373686; = p.P33L on NM_001005236.3) | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100542206; called by muse, mutect2, varscan2
- OR2G3 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100180418, COSV60681574; called by muse, mutect2, varscan2
- OR6K6 | c.94G>A p.G32R (on ENST00000368144; = p.G8R on NM_001005184.1) | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs141465999; called by muse, mutect2, varscan2
- OR8B4 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62070615; called by muse, mutect2, varscan2
- PAH | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 100/636 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100187908; called by muse, mutect2, varscan2
- PAK5 | c.2086G>T p.G696* | Nonsense Mutation (SNP) | VAF 62/220 reads (28%) | catalogued as COSV62022910; called by muse, mutect2, varscan2
- PAK5 | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1416163895, COSV62026355, COSV62029552; called by muse, mutect2, varscan2
- PAK5 | c.137del p.T46Rfs*22 | Frame Shift Del (DEL) | VAF 53/185 reads (29%) | catalogued as COSV62028649; called by mutect2, pindel, varscan2
- PARD3B | c.3271G>T p.A1091S (on ENST00000406610 / NM_001302769.2; = p.A1022S on NM_057177.7) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.089); catalogued as COSV104414951; called by muse, mutect2, varscan2
- PAX4 | c.915C>A p.G305= | Splice Region (SNP) | VAF 112/353 reads (32%) | catalogued as rs757705365; called by muse, mutect2, varscan2
- PCDH11X | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 152/262 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100012207; called by mutect2, varscan2
- PCDH15 | c.3101G>T p.R1034L | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as rs907693214, CM163812, COSV57270708; called by muse, mutect2, varscan2
- PCDH17 | c.1607C>A p.A536D | Missense Mutation (SNP) | VAF 154/336 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64980274; called by muse, mutect2, varscan2
- PCDH19 | c.1821G>T p.M607I | Missense Mutation (SNP) | VAF 244/394 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55268862; called by muse, mutect2, varscan2
- PCDHA9 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 161/349 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.087); catalogued as COSV65326351; called by muse, mutect2, varscan2
- PCDHGA9 | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.117); catalogued as COSV54043223; called by muse, mutect2, varscan2
- PCK1 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs1186142819, COSV60127076; called by muse, mutect2, varscan2
- PEX5L | c.1133C>A p.A378E | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs979357869; called by muse, mutect2, varscan2
- PFDN5 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54475184, COSV99229210; called by muse, mutect2, varscan2
- PKDREJ | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV53546182; called by muse, mutect2, varscan2
- PKHD1L1 | c.5189G>C p.G1730A | Missense Mutation (SNP) | VAF 114/210 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs770656828, COSV65741476; called by muse, mutect2, varscan2
- PKLR | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 219/692 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM090466; called by muse, mutect2, varscan2
- PKP1 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 232/791 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55820327; called by muse, mutect2, varscan2
- PLEKHA5 | c.432+1G>A p.X144_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as COSV54705769; called by muse, mutect2, varscan2
- PLEKHA7 | c.1430C>T p.T477I | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as rs1279595649; called by muse, varscan2
- PLPPR4 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100926707; called by muse, mutect2, varscan2
- PMP2 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56266967; called by muse, mutect2, varscan2
- PNPLA3 | c.943A>G p.S315G | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53378361; called by muse, mutect2, varscan2
- POTEE | c.495C>A p.D165E | Missense Mutation (SNP) | VAF 103/488 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV58224170; called by muse, mutect2, varscan2
- POTEG | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 177/1501 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV101611975; called by muse, mutect2, varscan2
- PPP1R16B | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 72/139 reads (52%) | catalogued as COSV100239272; called by muse, mutect2, varscan2
- PRAME | c.856G>C p.A286P | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.819); catalogued as COSV67160862, COSV67161023; called by muse, mutect2, varscan2
- PRDM15 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752309557; called by muse, mutect2, varscan2
- PREX2 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1429693114; called by muse, mutect2
- PROSER3 | c.924G>T p.W308C | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs907280072, COSV56553976; called by muse, mutect2, varscan2
- PRPF6 | c.2262G>T p.E754D | Missense Mutation (SNP) | VAF 195/910 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV53872557; called by muse, mutect2, varscan2
- PRR27 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV60641677; called by muse, mutect2, varscan2
- PTCH2 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs768496761, COSV100942147; called by muse, mutect2, varscan2
- PTPRN2 | c.2065C>A p.R689S | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs770942637; called by muse, mutect2, varscan2
- PYHIN1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932383; called by muse, mutect2, varscan2
- RAB29 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 111/419 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1372871032, COSV52520894; called by muse, mutect2, varscan2
- RACGAP1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs756383824; called by muse, mutect2, varscan2
- RBFOX3 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 50/126 reads (40%) | catalogued as rs868697775; called by muse, mutect2, varscan2
- RFC4 | c.132-5G>T | Splice Region (SNP) | VAF 38/189 reads (20%) | catalogued as rs778205938; called by muse, mutect2, varscan2
- RFC4 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs146612878; called by muse, varscan2
- RP1 | c.1315C>G p.Q439E | Missense Mutation (SNP) | VAF 502/737 reads (68%) | SIFT tolerated (0.79); PolyPhen benign (0.041); catalogued as rs760098833; called by muse, mutect2, varscan2
- RPTOR | c.2693G>T p.S898I | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV60821702; called by muse, mutect2, varscan2
- RUFY1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99057842; called by muse, mutect2, varscan2
- SAPCD2 | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 32/121 reads (26%) | catalogued as COSV101294026; called by muse, mutect2, varscan2
- SBF1 | c.3865C>T p.P1289S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.325); catalogued as rs1299041822; called by muse, mutect2, varscan2
- SCN11A | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs764550088, COSV56567140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs35393929; called by muse, mutect2, varscan2
- SELENOO | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs763667029; called by muse, varscan2
- SEMA5A | c.2034G>C p.R678S | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66784783; called by muse, varscan2
- SERPINB12 | c.903del p.F302Sfs*? | Frame Shift Del (DEL) | VAF 56/219 reads (26%) | catalogued as COSV54034203, COSV99501799; called by mutect2, pindel, varscan2
- SEZ6L2 | c.701G>T p.G234V (on ENST00000308713 / NM_001114099.3; = p.G164V on NM_012410.4) | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1225405607, COSV100435729; called by muse, mutect2, varscan2
- SIN3A | c.3289-1G>T p.X1097_splice | Splice Site (SNP) | VAF 81/231 reads (35%) | catalogued as COSV100845169; called by muse, mutect2, varscan2
- SIN3B | c.3151G>T p.A1051S | Missense Mutation (SNP) | VAF 123/211 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as rs1487761010, COSV104372612; called by muse, mutect2, varscan2
- SLC12A2 | c.1309G>T p.V437F | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV104390041; called by muse, varscan2
- SLC25A13 | c.16-1G>A p.X6_splice | Splice Site (SNP) | VAF 34/162 reads (21%) | catalogued as rs774759392, CS065618; called by muse, mutect2, varscan2
- SLC25A42 | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV59380774; called by muse, mutect2, varscan2
- SLC26A6 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs1407648475; called by muse, mutect2, varscan2
- SLC5A8 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV73310913; called by muse, mutect2, varscan2
- SOBP | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100433430; called by muse, mutect2, varscan2
- SOD1 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM1312320, CM148511, CP035469; called by muse, mutect2, varscan2
- SORCS3 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63817042; called by muse, mutect2, varscan2
- SORCS3 | c.3530C>G p.A1177G | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV63824237; called by muse, mutect2, varscan2
- SPATA17 | c.896A>T p.H299L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs549452959; called by muse, varscan2
- SPATA31A6 | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 259/949 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.513); catalogued as rs1353768803; called by muse, mutect2, varscan2
- SPATA31A6 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 185/662 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.236); catalogued as rs767655212; called by muse, mutect2, varscan2
- SPATA31A7 | c.1905G>C p.Q635H | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as rs1276191692; called by mutect2, varscan2
- SPATA31D1 | c.2419A>G p.T807A | Missense Mutation (SNP) | VAF 150/377 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as COSV61195162, COSV61200743; called by muse, mutect2, varscan2
- SPTA1 | c.3703C>G p.L1235V | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100935077; called by muse, mutect2, varscan2
- SSTR4 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV54797819; called by muse, mutect2, varscan2
- ST7 | c.432G>C p.R144S | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99621818; called by muse, mutect2, varscan2
- TAB1 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 131/314 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768487425; called by muse, mutect2, varscan2
- TAF1L | c.2001G>C p.K667N | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54261217; called by muse, mutect2, varscan2
- TARS1 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV54311376; called by muse, mutect2, varscan2
- TBX15 | c.321G>T p.M107I (on ENST00000369429 / NM_001330677.2; = p.M1? on NM_152380.3) | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs747616769; called by muse, mutect2, varscan2
- TDRD15 | c.5341A>G p.I1781V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1176116845; called by muse, mutect2, varscan2
- TEK | c.2761G>T p.E921* | Nonsense Mutation (SNP) | VAF 195/733 reads (27%) | catalogued as COSV66232749; called by muse, mutect2, varscan2
- TEX11 | c.1510G>C p.E504Q (on ENST00000344304; = p.E489Q on NM_031276.3) | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); catalogued as rs1483378881, COSV60227962; called by muse, mutect2, varscan2
- THNSL2 | c.83del p.G28Afs*28 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | catalogued as COSV59082141; called by mutect2*, pindel, varscan2*
- TIAM2 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 149/275 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs773735310; called by muse, mutect2, varscan2
- TMEM132B | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 166/387 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54754884; called by muse, mutect2, varscan2
- TMEM132B | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1302625173; called by muse, mutect2, varscan2
- TMEM196 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV101337495; called by muse, mutect2, varscan2
- TMEM232 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs374220227; called by muse, mutect2, varscan2
- TMTC3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1351121213; called by muse, mutect2, varscan2
- TNFSF11 | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV53478996; called by muse, mutect2, varscan2
- TRAV29DV5 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as rs1247364558; called by muse, mutect2, varscan2
- TRBV2 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1410491884; called by muse, mutect2, varscan2
- TRGV5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 89/335 reads (27%) | catalogued as rs767852255; called by muse, mutect2, varscan2
- TRHR | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 49/356 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV61235257; called by muse, mutect2, varscan2
- TRIM36 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs957625882, COSV56690712; called by muse, mutect2, varscan2
- TRIM67 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.051); catalogued as rs1199407875; called by muse, mutect2, varscan2
- TRPM6 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 134/321 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777702496; called by muse, mutect2, varscan2
- TSHZ3 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV53682502; called by muse, mutect2, varscan2
- TTC28 | c.1583G>C p.G528A | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1314184903; called by muse, mutect2, varscan2
- TTLL13P | c.596A>T p.Y199F | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0.035); catalogued as rs141226431; called by muse, mutect2, varscan2
- TWNK | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 151/499 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as rs954019330; called by muse, mutect2, varscan2
- USH2A | c.3180del p.R1061Efs*51 | Frame Shift Del (DEL) | VAF 75/316 reads (24%) | catalogued as COSV56352811; called by pindel, varscan2
- VSTM2A | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761935287, COSV56496047; called by muse, mutect2, varscan2
- XIRP2 | c.5575C>G p.Q1859E (on ENST00000628543; = p.Q2034E on NM_152381.6) | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs766769044; called by muse, mutect2, varscan2
- XRCC2 | c.714G>C p.R238S | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as rs534746330, COSV100831721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBTB10 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 243/401 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV100990222; called by muse, mutect2, varscan2
- ZC4H2 | c.210C>A p.H70Q | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62004355; called by muse, mutect2, varscan2
- ZDHHC19 | c.390G>C p.W130C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs550075729; called by muse, mutect2, varscan2
- ZFPL1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51868886, COSV51869999; called by muse, mutect2, varscan2
- ZFPM2 | c.2481C>A p.D827E | Missense Mutation (SNP) | VAF 128/530 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV65872371; called by muse, mutect2, varscan2
- ZNF121 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs1220749501; called by muse, mutect2, varscan2
- ZNF268 | c.834C>A p.C278* | Nonsense Mutation (SNP) | VAF 34/179 reads (19%) | catalogued as COSV99934774; called by muse, mutect2, varscan2
- ZNF300 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 58/135 reads (43%) | catalogued as COSV51044423; called by muse, mutect2, varscan2
- ZNF384 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60531537; called by muse, mutect2, varscan2
- ZNF423 | c.2527G>C p.A843P (on ENST00000563137 / NM_001379286.1; = p.A835P on NM_015069.4) | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52188968; called by muse, mutect2, varscan2
- ZNF516 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV71587368; called by muse, mutect2, varscan2
- ZNF675 | c.1159A>T p.R387W | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1376542802; called by muse, mutect2, varscan2
- ZNF700 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 63/138 reads (46%) | catalogued as COSV54311848; called by muse, mutect2, varscan2
- ZNF853 | c.1598G>C p.R533P | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV71922823; called by muse, mutect2, varscan2
- ZNF91 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.147); catalogued as rs757869359, COSV56084836; called by muse, mutect2, varscan2
- ABCC8 | c.823-6G>T | Splice Region (SNP) | VAF 106/350 reads (30%) | called by muse, mutect2, varscan2
- AC245033.1 | c.1521G>T p.M507I | Missense Mutation (SNP) | VAF 172/436 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2
- ACCS | c.1238G>T p.W413L | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ACP7 | c.55T>A p.L19M | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSF2 | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSS1 | c.1445A>T p.D482V | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ACTR3B | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM11 | c.1617+1G>T p.X539_splice | Splice Site (SNP) | VAF 60/215 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 132/654 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, varscan2
- ADAMTS16 | c.1426C>A p.R476S | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADAMTS20 | c.5332T>C p.C1778R | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS20 | c.4756C>G p.P1586A | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTS5 | c.1603C>A p.P535T | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS5 | c.69del p.A24Rfs*142 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS7 | c.1882C>G p.P628A | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, varscan2
- ADAMTS8 | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ADGB | c.4095G>C p.L1365F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ADGRB3 | c.2972C>A p.P991Q | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADSS2 | c.972G>T p.R324S | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- AEBP1 | c.1901T>A p.L634Q | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AFAP1L1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- AHCYL2 | c.1664A>T p.E555V | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AHNAK2 | c.10272G>T p.K3424N | Missense Mutation (SNP) | VAF 208/420 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- AHRR | c.1562A>T p.D521V | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AK5 | c.666A>T p.R222S (on ENST00000354567 / NM_174858.3; = p.R196S on NM_012093.4) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKR1B10 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 133/320 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- AKR1B15 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 63/516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKR1C3 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKR1C8P | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AL121899.2 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- AL445989.1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 201/481 reads (42%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- ALDH1B1 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.138); called by muse, mutect2
- ALDH1L2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALDH6A1 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 124/276 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ALPK2 | c.3848C>A p.A1283D | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AMY2A | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.4402G>T p.E1468* | Nonsense Mutation (SNP) | VAF 159/360 reads (44%) | called by muse, mutect2, varscan2
- ANK2 | c.5828G>T p.G1943V | Missense Mutation (SNP) | VAF 125/253 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ANKAR | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.1219A>C p.T407P | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO1 | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO4 | c.1776C>A p.F592L (on ENST00000392977 / NM_001286615.2; = p.F557L on NM_178826.4) | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ANPEP | c.1454G>T p.R485M | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APOB | c.11706G>T p.L3902F | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- APOB | c.5474G>T p.G1825V | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOBEC1 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- APOBR | c.973G>T p.G325W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2
- APOL6 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 82/199 reads (41%) | called by muse, mutect2, varscan2
- ARFIP1 | c.203-1G>T p.X68_splice | Splice Site (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.1126A>G p.S376G | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGEF28 | c.4333C>T p.H1445Y | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARID2 | c.1445G>T p.R482M | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARID4B | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ARMC5 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 81/467 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARMH3 | c.1741del p.E581Kfs*6 | Frame Shift Del (DEL) | VAF 62/250 reads (25%) | called by mutect2, pindel, varscan2
- ASAH2 | c.330C>A p.D110E | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASAP1 | c.3328G>T p.E1110* | Nonsense Mutation (SNP) | VAF 54/264 reads (20%) | called by muse, mutect2, varscan2
- ASMT | c.957G>T p.M319I (on ENST00000381229; = p.M347I on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 633/1169 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ASPM | c.1180A>T p.N394Y | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ATG9B | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ATP10D | c.1459A>T p.S487C | Missense Mutation (SNP) | VAF 198/405 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATP1A4 | c.2657C>A p.P886H | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8A2 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP8B2 | c.161G>T p.R54L (on ENST00000672630; = p.R21L on NM_001005855.2) | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATXN7L3 | c.790G>C p.D264H (on ENST00000389384 / NM_001382309.1; = p.D271H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- AXL | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- B3GALT2 | c.848T>A p.M283K | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- BAHCC1 | c.3790G>C p.G1264R | Missense Mutation (SNP) | VAF 131/264 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- BARHL2 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.196); called by mutect2, varscan2
- BAZ2B | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- BBS12 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND3 | c.1323G>C p.Q441H | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- BHMG1 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- BMPER | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 118/406 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- BNC2 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 113/255 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- BRAF | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRCA2 | c.3947A>T p.N1316I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C10orf67 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- C10orf71 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- C16orf70 | c.959A>T p.N320I | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C16orf71 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C18orf63 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- C1QL3 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- C1QTNF9B | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 88/432 reads (20%) | called by muse, varscan2
- C7 | c.231A>T p.R77S | Missense Mutation (SNP) | VAF 67/339 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- C7 | c.1387G>T p.G463C | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C9 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1B | c.1964C>A p.T655N | Missense Mutation (SNP) | VAF 97/321 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1B | c.3743_3744delinsT p.K1248Ifs*3 | Frame Shift Del (DEL) | VAF 43/255 reads (17%) | called by pindel, varscan2*
- CACNA1G | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNA2D1 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, varscan2
- CALN1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAMK1D | c.1039+1G>C p.X347_splice (on ENST00000619168 / NM_153498.4; = p.C347S on NM_020397.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 39/179 reads (22%) | called by muse, varscan2
- CAMK2D | c.1434-1G>T p.X478_splice | Splice Site (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- CAPN14 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASS4 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBLL2 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC141 | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CCDC152 | c.-2G>T | Splice Region (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- CCDC27 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CCDC42 | c.389A>T p.Q130L | Missense Mutation (SNP) | VAF 295/474 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCER1 | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCHCR1 | c.1900+5G>T | Splice Region (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- CCNF | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCSAP | c.233del p.P78Rfs*8 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- CD109 | c.3363G>T p.M1121I | Missense Mutation (SNP) | VAF 132/246 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CD163 | c.1564G>T p.G522C | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD226 | c.992G>T p.R331I | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CDC14C | c.1201C>A p.L401M (on ENST00000428251; = p.L294M on NM_152627.3) | Missense Mutation (SNP) | VAF 87/494 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CDH12 | c.227del p.G76Efs*7 | Frame Shift Del (DEL) | VAF 78/306 reads (25%) | called by mutect2, pindel
- CDH18 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 120/596 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CDH4 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH8 | c.755A>T p.H252L | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH9 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 107/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CDHR1 | c.2423A>C p.Q808P | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDHR4 | c.1483G>T p.G495W | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEL | c.101G>T p.G34V (on ENST00000673714; = p.G31V on NM_001807.6) | Missense Mutation (SNP) | VAF 116/594 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CENPU | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CEP192 | c.2645G>T p.C882F | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP83 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CFAP43 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- CFAP58 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CFAP69 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- CHAT | c.1204C>A p.H402N | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD8 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CHI3L1 | c.1012-8C>A | Splice Region (SNP) | VAF 43/144 reads (30%) | called by muse, mutect2, varscan2
- CHRM3 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHST3 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 178/502 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CLCA1 | c.2462C>A p.S821Y | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CLDN17 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CLEC12B | c.782G>T p.W261L | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CLMN | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CLP1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CMA1 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, varscan2
- CMIP | c.988G>T p.V330L (on ENST00000537098 / NM_198390.2; = p.V236L on NM_030629.3) | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CNDP1 | c.1293_1294dup p.R432Kfs*14 | Frame Shift Ins (INS) | VAF 45/147 reads (31%) | called by mutect2, pindel, varscan2
- CNTN5 | c.2735G>T p.G912V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.31); called by mutect2, varscan2
- CNTNAP2 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 109/305 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP3 | c.3262C>A p.P1088T | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COL13A1 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL18A1 | c.2040G>T p.E680D (on ENST00000359759 / NM_130444.3; = p.E445D on NM_030582.4) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL22A1 | c.4433C>A p.T1478N | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- COL28A1 | c.1582-1G>T p.X528_splice | Splice Site (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- COL4A2 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 391/596 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL5A1 | c.1720G>T p.G574C | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL5A2 | c.1275T>A p.D425E | Missense Mutation (SNP) | VAF 110/296 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- COL5A2 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- COL6A5 | c.1234A>G p.K412E | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- COP1 | c.1688del p.F563Sfs*46 | Frame Shift Del (DEL) | VAF 84/290 reads (29%) | called by mutect2, pindel, varscan2
- CORO7 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CP | c.1474T>A p.S492T | Missense Mutation (SNP) | VAF 73/420 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPN2 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 52/238 reads (22%) | called by muse, mutect2, varscan2
- CPNE8 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- CPPED1 | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 100/186 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CR1 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CREB5 | c.838C>A p.Q280K (on ENST00000357727 / NM_182898.4; = p.Q273K on NM_004904.3) | Missense Mutation (SNP) | VAF 175/575 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CRISPLD2 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYGD | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CSF2RA | c.145T>C p.W49R | Missense Mutation (SNP) | VAF 151/1184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.2578T>A p.C860S (on ENST00000297405 / NM_001363185.1; = p.C756S on NM_052900.3) | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSPG4 | c.6179C>A p.T2060N | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CST2 | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 134/398 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- CST4 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 103/480 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- CTC1 | c.2225T>A p.M742K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CTNNA2 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, varscan2
- CTNND2 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 105/447 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUBN | c.8044G>C p.A2682P | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CUX1 | c.4043G>T p.G1348V | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- CYRIB | c.840+1G>T p.X280_splice | Splice Site (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- DAZAP1 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 102/194 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DBF4 | c.1699del p.D567Ifs*12 | Frame Shift Del (DEL) | VAF 30/138 reads (22%) | called by mutect2, pindel*, varscan2
- DBNDD2 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- DCAF4L2 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 200/380 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- DDX18 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DDX60L | c.3732del p.I1245Lfs*21 | Frame Shift Del (DEL) | VAF 20/113 reads (18%) | called by mutect2, pindel, varscan2
- DEK | c.329A>T p.H110L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DENND4A | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 86/347 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGKG | c.862T>A p.C288S | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.3052A>G p.R1018G | Missense Mutation (SNP) | VAF 82/135 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- DIO2 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- DISC1 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 103/360 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- DKK3 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 127/403 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- DLG2 | c.1468del p.A490Lfs*5 | Frame Shift Del (DEL) | VAF 81/214 reads (38%) | called by mutect2, pindel, varscan2
- DMBT1 | c.3137_3138insT p.R1047Pfs*13 (on ENST00000338354 / NM_001377530.1; = p.R548Pfs*13 on NM_004406.3) | Frame Shift Ins (INS) | VAF 184/676 reads (27%) | called by mutect2, varscan2
- DMBT1 | c.3141dup p.F1048Vfs*12 (on ENST00000338354 / NM_001377530.1; = p.F549Vfs*12 on NM_004406.3) | Frame Shift Ins (INS) | VAF 217/712 reads (30%) | called by mutect2*, pindel, varscan2*
- DMD | c.10847C>T p.T3616I | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2
- DMD | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 160/287 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNA2 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.051); called by muse, mutect2
- DNAH12 | c.7455G>T p.K2485N (on ENST00000351747; = p.K3353N on NM_001366028.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- DNAH9 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAI3 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- DNAJC12 | c.279G>T p.L93F | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNMT3B | c.1245G>T p.Q415H | Missense Mutation (SNP) | VAF 139/295 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- DNTTIP1 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- DOCK3 | c.2519C>G p.T840R | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DPH6 | c.256A>T p.T86S | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP6 | c.1646T>A p.F549Y (on ENST00000377770 / NM_001364500.2; = p.F487Y on NM_001936.5) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPPA2 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DPY19L4 | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUOX2 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 177/614 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- DYNC2H1 | c.10663G>A p.V3555I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- DYNC2LI1 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2
- EIF3A | c.4131G>T p.W1377C | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EIPR1 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.112); called by muse, mutect2
- ELAPOR2 | c.2165A>T p.H722L (on ENST00000450689 / NM_001142749.3; = p.H555L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, varscan2
- ELFN1 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EMC9 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- EML4 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ENAM | c.3359del p.P1120Hfs*38 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- ENPP1 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 107/214 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ENTR1 | c.271del p.H91Tfs*25 | Frame Shift Del (DEL) | VAF 55/200 reads (28%) | called by mutect2, pindel, varscan2
- EPC2 | c.827del p.G276Efs*11 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- EPHA3 | c.574T>A p.L192M | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPN1 | c.888G>T p.W296C (on ENST00000270460 / NM_001321263.1; = p.W271C on NM_013333.3) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EPRS1 | c.3300+1G>T p.X1100_splice | Splice Site (SNP) | VAF 56/179 reads (31%) | called by mutect2, varscan2
- ERP44 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ESCO2 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 115/223 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESRRG | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); called by muse, mutect2
- EXT1 | c.1768G>T p.V590L | Missense Mutation (SNP) | VAF 260/492 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- EYS | c.5967dup p.G1990Rfs*56 | Frame Shift Ins (INS) | VAF 93/196 reads (47%) | called by mutect2, pindel, varscan2
- EYS | c.4452G>T p.W1484C | Missense Mutation (SNP) | VAF 183/351 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- F13A1 | c.1690G>T p.V564F | Missense Mutation (SNP) | VAF 290/444 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM110B | c.809T>A p.V270E | Missense Mutation (SNP) | VAF 118/438 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- FAM120B | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 102/178 reads (57%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM135B | c.3823G>T p.G1275W | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM155B | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 149/248 reads (60%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM160B2 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM209B | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 151/508 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM210A | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 121/447 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM222A | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FAM47A | c.1670A>T p.H557L | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM47C | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM71B | c.1366A>T p.R456* | Nonsense Mutation (SNP) | VAF 105/208 reads (50%) | called by muse, mutect2, varscan2
- FANCG | c.1076+6G>T | Splice Region (SNP) | VAF 126/431 reads (29%) | called by muse, mutect2, varscan2
- FASLG | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 162/518 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FAT3 | c.12780C>A p.H4260Q | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FCER2 | c.379+2T>A p.X127_splice | Splice Site (SNP) | VAF 93/177 reads (53%) | called by muse, mutect2, varscan2
- FCRL6 | c.666C>A p.D222E | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FER1L6 | c.4618G>T p.E1540* | Nonsense Mutation (SNP) | VAF 56/485 reads (12%) | called by muse, mutect2, varscan2
- FGD6 | c.2812G>T p.E938* | Nonsense Mutation (SNP) | VAF 66/160 reads (41%) | called by muse, mutect2, varscan2
- FIGNL1 | c.1837A>G p.R613G | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FMN2 | c.2098dup p.L700Pfs*13 | Frame Shift Ins (INS) | VAF 86/226 reads (38%) | called by mutect2, pindel, varscan2
- FMN2 | c.3080G>C p.G1027A | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.177); called by muse, varscan2
- FOCAD | c.884A>T p.H295L | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOXM1 | c.1069A>T p.T357S | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FPR3 | c.578T>G p.V193G | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2
- FRAS1 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, varscan2
- FRMPD4 | c.319+1G>T p.X107_splice | Splice Site (SNP) | VAF 36/63 reads (57%) | called by mutect2, varscan2
- FSIP2 | c.11695A>T p.K3899* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- FXYD6 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- GABBR1 | c.2567A>G p.K856R | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GALNT7 | c.1067G>T p.W356L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GAS2L1 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 146/429 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCKR | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 180/446 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GCN1 | c.1807G>T p.G603* | Nonsense Mutation (SNP) | VAF 26/177 reads (15%) | called by muse, mutect2, varscan2
- GDF2 | c.921C>G p.H307Q | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GFI1B | c.459C>A p.S153R | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GIMAP1 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GIMAP6 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 135/476 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GK5 | c.780A>T p.E260D | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GLDC | c.566T>G p.L189R | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GLI1 | c.2094G>T p.M698I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GMNC | c.645T>A p.H215Q | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- GNAO1 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- GNGT2 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GNL1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 60/98 reads (61%) | called by muse, mutect2, varscan2
- GPAM | c.1613A>T p.Q538L | Missense Mutation (SNP) | VAF 133/502 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR25 | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GPR26 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); called by muse, varscan2
- GPRC6A | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GRIK3 | c.2565+4A>T | Splice Region (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- GRIK5 | c.2021C>A p.T674N | Missense Mutation (SNP) | VAF 142/218 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- GRIN2B | c.446C>A p.S149* | Nonsense Mutation (SNP) | VAF 45/129 reads (35%) | called by muse, mutect2, varscan2
- GRM5 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GRM7 | c.1903G>T p.G635C | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM8 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 109/379 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSTA5 | c.395A>T p.Y132F | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GSTA5 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- GTF2H4 | c.21G>C p.R7S | Missense Mutation (SNP) | VAF 183/357 reads (51%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GTF3C1 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 64/194 reads (33%) | called by muse, mutect2, varscan2
- GUCA1A | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 342/619 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1B1 | c.19C>T p.H7Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- HAS1 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HECW1 | c.4538G>T p.R1513L | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HEMGN | c.296A>T p.K99I | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- HERC1 | c.9110G>T p.G3037V | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- HGF | c.793G>C p.G265R | Missense Mutation (SNP) | VAF 118/447 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HHLA1 | c.1553C>A p.T518N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HHLA1 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- HIVEP3 | c.6319G>T p.G2107W | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- HIVEP3 | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- HMCN1 | c.7010A>C p.K2337T | Missense Mutation (SNP) | VAF 72/517 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- HMCN2 | c.5779T>A p.W1927R | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HMCN2 | c.10397T>A p.L3466Q | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.12334C>G p.R4112G | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- HMCN2 | c.12535G>A p.A4179T | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- HNF4G | c.982+1G>T p.X328_splice (on ENST00000354370 / NM_001330561.2; = p.X375_splice on NM_004133.5) | Splice Site (SNP) | VAF 146/238 reads (61%) | called by mutect2, varscan2
- HOXA2 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD3B1 | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- HSF5 | c.69C>A p.N23K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HSP90AB1 | c.2059G>T p.G687C | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- HTR3E | c.320G>T p.C107F (on ENST00000415389 / NM_001256613.1; = p.C122F on NM_182589.2) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- HTR7 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- HTT | c.7849-1G>T p.X2617_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- HYDIN | c.6622G>T p.V2208L | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HYKK | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ICAM5 | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 108/203 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ICE1 | c.277_278insT p.G93Vfs*35 | Frame Shift Ins (INS) | VAF 17/111 reads (15%) | called by mutect2, pindel*, varscan2
- IGDCC4 | c.2650C>A p.L884M | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by mutect2, varscan2
- IGHV1-45 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- IGKV1-27 | c.147G>C p.Q49H | Missense Mutation (SNP) | VAF 112/428 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- IGLC2 | c.233A>T p.Q78L | Missense Mutation (SNP) | VAF 155/2416 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); called by muse, mutect2
- IGLC3 | c.233A>T p.Q78L | Missense Mutation (SNP) | VAF 83/1577 reads (5%) | PolyPhen benign (0.426); called by muse, mutect2
- IGLV2-14 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 83/308 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- IGLV2-33 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 85/292 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- IGLV3-22 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF1 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 80/119 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL12B | c.364+1G>T p.X122_splice | Splice Site (SNP) | VAF 61/149 reads (41%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1731G>T p.E577D | Missense Mutation (SNP) | VAF 118/193 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- IL21R | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- IL3RA | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ILDR2 | c.1679C>A p.P560Q | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ILDR2 | c.1453C>A p.R485S | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INAVA | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- INAVA | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2
- INPP5A | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- INSRR | c.3722A>G p.H1241R | Missense Mutation (SNP) | VAF 145/458 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- INTS10 | c.664+8G>A | Splice Region (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- INTS13 | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IQGAP2 | c.3661-1G>T p.X1221_splice | Splice Site (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- IQSEC3 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 83/594 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ITGA2B | c.2651A>T p.H884L | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ITGAD | c.2906G>T p.W969L | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ITGB2 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ITIH5 | c.1723C>G p.R575G | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ITPA | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 239/551 reads (43%) | called by muse, mutect2, varscan2
- IVL | c.1457A>T p.Q486L | Missense Mutation (SNP) | VAF 95/347 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- JMJD1C | c.6558del p.W2186* | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- KANK4 | c.1835C>A p.S612* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | called by muse, varscan2
- KCNA6 | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KCNB2 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KCNC2 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KCNH3 | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK12 | c.865T>A p.C289S | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KCNMA1 | c.2855C>T p.S952F (on ENST00000286628 / NM_001161352.2; = p.S894F on NM_002247.4) | Missense Mutation (SNP) | VAF 162/452 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- KCNV1 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 54/407 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1109 | c.9956G>T p.G3319V | Missense Mutation (SNP) | VAF 221/498 reads (44%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- KIAA1109 | c.12479A>G p.Y4160C | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KIAA1210 | c.3139G>T p.E1047* | Nonsense Mutation (SNP) | VAF 87/158 reads (55%) | called by muse, mutect2, varscan2
- KIAA2026 | c.2403G>C p.R801S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- KIF19 | c.2233G>T p.D745Y | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21B | c.3162G>T p.Q1054H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- KIF26A | c.3923G>T p.R1308M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIRREL1 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLB | c.728A>T p.Y243F | Missense Mutation (SNP) | VAF 75/125 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- KLHL1 | c.1481G>C p.G494A | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- KPNA5 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KPNA5 | c.1125+1G>T p.X375_splice | Splice Site (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- KRT26 | c.833T>G p.F278C | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT31 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KRT33A | c.746C>A p.T249K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KRT36 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 158/543 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT40 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KRTAP10-8 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KRTAP4-11 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 158/588 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, varscan2
- KRTAP4-4 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KTN1 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- LAMA3 | c.8287G>A p.D2763N (on ENST00000313654 / NM_198129.4; = p.D1154N on NM_000227.6) | Missense Mutation (SNP) | VAF 156/504 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LAMB4 | c.3368G>T p.G1123V | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LILRA4 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 155/288 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMTK2 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 65/285 reads (23%) | called by muse, mutect2, varscan2
- LMX1A | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- LOXHD1 | c.4213G>C p.G1405R | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LOXHD1 | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXL3 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LPIN2 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 72/518 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN5 | c.1498A>T p.T500S | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRP4 | c.4803G>T p.M1601I | Missense Mutation (SNP) | VAF 219/468 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- LRRC24 | c.894G>C p.Q298H | Missense Mutation (SNP) | VAF 37/452 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2
- LRRC47 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- LRRC4C | c.1063G>T p.V355L | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- LRRC6 | c.1044+1G>T p.X348_splice | Splice Site (SNP) | VAF 69/141 reads (49%) | called by muse, mutect2, varscan2
- LRRC74A | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRRIQ1 | c.3245C>A p.S1082* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- LYST | c.2220A>T p.Q740H | Missense Mutation (SNP) | VAF 131/219 reads (60%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYZL2 | c.515+1G>A p.X172_splice (on ENST00000375318; = p.X126_splice on NM_183058.3) | Splice Site (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- MAB21L4 | c.1160G>T p.R387L (on ENST00000388934 / NM_001085437.3; = p.R219L on NM_024861.4) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- MAGEC1 | c.2657T>C p.L886P | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- MAGI3 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAIP1 | c.651G>C p.L217F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MAN2A1 | c.3196G>T p.A1066S | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MAP1B | c.6218C>A p.P2073H | Missense Mutation (SNP) | VAF 89/241 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP2 | c.5156-1G>T p.X1719_splice | Splice Site (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2
- MARS2 | c.1482G>T p.K494N | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAST2 | c.1781-2A>T p.X594_splice | Splice Site (SNP) | VAF 48/135 reads (36%) | called by muse, mutect2, varscan2
- MAST4 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2
- MATK | c.476G>T p.C159F (on ENST00000310132 / NM_139355.3; = p.C160F on NM_002378.4) | Missense Mutation (SNP) | VAF 123/215 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCTP2 | c.2212A>G p.S738G | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCUB | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDGA2 | c.1387G>C p.D463H (on ENST00000399232 / NM_001113498.2; = p.D165H on NM_182830.4) | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MED7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- METTL25 | c.1404G>T p.G468= | Splice Region (SNP) | VAF 55/138 reads (40%) | called by muse, mutect2, varscan2
- METTL27 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MFGE8 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.2006T>A p.L669H | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MIER1 | c.220G>T p.G74C (on ENST00000355356 / NM_001077701.3; = p.G91C on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIGA2 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 84/245 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MKS1 | c.959-2A>T p.X320_splice | Splice Site (SNP) | VAF 134/486 reads (28%) | called by muse, mutect2, varscan2
- MMP10 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MRPS31 | c.833G>T p.W278L | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTA2 | c.1842G>T p.R614S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MTMR11 | c.607G>T p.E203* (on ENST00000439741 / NM_001145862.2; = p.E131* on NM_181873.3) | Nonsense Mutation (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- MTMR11 | c.606G>T p.W202C (on ENST00000439741 / NM_001145862.2; = p.W130C on NM_181873.3) | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.4753del p.H1585Ifs*63 | Frame Shift Del (DEL) | VAF 109/212 reads (51%) | called by mutect2, pindel, varscan2
- MUC16 | c.2323C>G p.L775V | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MUC17 | c.12188C>A p.P4063Q | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYF6 | c.695A>T p.K232I | Missense Mutation (SNP) | VAF 101/354 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYH1 | c.3535C>A p.R1179S | Missense Mutation (SNP) | VAF 352/589 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- MYLK | c.4429C>A p.Q1477K | Missense Mutation (SNP) | VAF 62/366 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- MYO5C | c.4219G>C p.A1407P | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MYO7B | c.6082A>T p.I2028F | Missense Mutation (SNP) | VAF 105/223 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- N4BP2 | c.1231dup p.W411Lfs*4 | Frame Shift Ins (INS) | VAF 159/322 reads (49%) | called by mutect2, pindel, varscan2
- NAT8L | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- NCAM1 | c.1766T>A p.L589H (on ENST00000316851 / NM_181351.5; = p.L579H on NM_000615.7) | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- NCAPH | c.504_505del p.V169Gfs*30 | Frame Shift Del (DEL) | VAF 40/157 reads (25%) | called by pindel, varscan2
- NCF4 | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 173/434 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
846 further variants in this file (347 protein-altering or splice-affecting, 300 silent, 199 other) are not listed here.
